Gene-level copy-number profile of tumor specimen C3N-03188-02 from CPTAC case C3N-03188, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.4 years (19,856 days).
Specimen C3N-03188-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc6a66e6-d052-48a2-a43a-09df37d938c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03188-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/b9729998-2cca-4715-b9ed-d5c9a2ce783e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 5; copy number 2: 2,121; copy number 3: 521; copy number 4: 41,830; copy number 5: 3,613; copy number 6: 8,204; copy number 7: 119; copy number 8: 1,070; copy number 9: 88; copy number 10: 1,285; copy number 13: 1; copy number 14: 24; copy number 304: 8.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–4): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,405 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,175,748–149,556,361, 6 genes, copy number 9–14: AC245297.3, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr7:6,161,776–76,919,191, 1,267 genes, copy number 10–304 (broad region; genes not listed).
- chr16:3,930,806–4,456,775, 20 genes, copy number 9: LINC02861, ADCY9, AC005736.1, AC009171.1, AC009171.2, SRL, LINC01569, TFAP4, GLIS2, GLIS2-AS1, PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN, DNAJA3, AC012676.3, AC012676.4, AC012676.2.
- chr19:13,731,760–14,370,196, 39 genes, copy number 9: CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.2, AC011509.1, LINC01841, LINC01842.
- chr19:46,480,796–46,601,200, 1 gene, copy number 9 (within-gene range 6–9): PPP5D1.
- chr19:46,558,641–47,113,776, 26 genes, copy number 9 (within-gene range 6–9): GAPDHP38, CALM3, AC093503.1, PTGIR, GNG8, AC093503.2, DACT3, DACT3-AS1, PRKD2, RN7SL364P, MIR320E, STRN4, AC008635.1, Y_RNA, FKRP, SLC1A5, AC008622.2, AC008622.3, HNRNPMP2, AC008622.1, AP2S1, ARHGAP35, AC008895.1, NPAS1, TMEM160, ZC3H4.
- chr19:49,462,752–49,888,750, 46 genes, copy number 10 (within-gene range 6–10): AC010619.1, FLT3LG, AC010619.2, RPL13A, SNORD32A, SNORD33, SNORD34, SNORD35A, RPS11, SNORD35B, MIR150, COX6CP7, FCGRT, RCN3, NOSIP, Y_RNA, PRRG2, PRR12, AC011495.2, RRAS, SCAF1, IRF3, BCL2L12, PRMT1, MIR5088, ADM5, AC011495.3, CPT1C, AC011495.1, TSKS, RNU6-841P, AP2A1, MIR6799, FUZ, AC006942.1, MED25, MIR6800, PTOV1-AS1, PTOV1, AC018766.1, MIR4749, PTOV1-AS2, PNKP, AKT1S1, TBC1D17, MIR4750.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
